Somatic mutation profile of tumor specimen MMRF_2401_2_BM_CD138pos (aliquot MMRF_2401_2_BM_CD138pos_T1_KHS5U_L13279) from MMRF case MMRF_2401, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.5 years (23,552 days).
Specimen MMRF_2401_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f342b742-4b2e-4474-874d-0a31bb925061.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2401_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2401_1_PB_CD3pos_C5_KHS5U_L12875; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc34c21c-5c1b-451e-8d9c-596147d18090

The open-access MAF lists 126 somatic variants for this specimen: 57 protein-altering or splice-affecting, 9 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 36, Intron 14, Silent 9, 5'UTR 4, Nonsense Mutation 3, 5'Flank 3, Splice Region 2, RNA 2, In Frame Del 2, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 41/98 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AR | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 85/98 reads (87%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.945); catalogued as COSV101017601; called by muse, mutect2, varscan2
- ATP6V1C1 | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 212/520 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as rs766755718; called by muse, varscan2
- CBLB | c.1410C>T p.C470= | Splice Region (SNP) | VAF 23/51 reads (45%) | catalogued as rs1213443450; called by muse, mutect2, varscan2
- GTSE1 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs765217704, COSV101483231; called by muse, varscan2
- IGHV2-70 | c.230A>C p.D77A | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs546960655; called by muse, varscan2
- IGLV3-25 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs189679814; called by muse, varscan2
- IGLV3-27 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 63/77 reads (82%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs761313604; called by muse, mutect2
- LRRIQ3 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770132340, COSV100598553, COSV63041590; called by muse, mutect2, varscan2
- MNX1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs774909386; called by muse, mutect2, varscan2
- NBPF3 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV59057695; called by muse, mutect2, varscan2
- PCDH9 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 81/110 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs1166291287; called by muse, varscan2
- PDP1 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1259886475; called by muse, mutect2, varscan2
- RAI1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV55390494; called by muse, mutect2, varscan2
- SLA2 | c.392_395del p.S131Cfs*77 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs770643107; called by mutect2, pindel, varscan2
- TOR4A | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV62627054; called by muse, mutect2, varscan2
- ADH1C | c.1021T>C p.F341L | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- BTBD11 | c.2543A>G p.E848G (on ENST00000280758 / NM_001018072.2; = p.E385G on NM_001017523.2) | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CCNB3 | c.1425G>T p.K475N | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CEP350 | c.1355C>G p.S452* | Nonsense Mutation (SNP) | VAF 72/250 reads (29%) | called by muse, mutect2, varscan2
- CFAP73 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- CIITA | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 98/281 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CKMT1B | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 79/121 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, varscan2
- CRYBG1 | c.2172A>T p.K724N | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DENND4B | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DGKB | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGR1 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA10 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 117/273 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FBXO42 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1289G>C p.G430A | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- FZD7 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GALR3 | c.884C>G p.S295W | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJA10 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- GRAMD4 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2
- GRIN2C | c.2606G>A p.G869E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HOXA13 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IGHA1 | c.385del p.L129Cfs*11 | Frame Shift Del (DEL) | VAF 53/127 reads (42%) | called by mutect2, pindel, varscan2
- IGHV2-70 | c.246_248del p.S83del | In Frame Del (DEL) | VAF 36/150 reads (24%) | called by pindel, varscan2
- IGHV2-70D | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- IGLV3-27 | c.337A>T p.N113Y | Missense Mutation (SNP) | VAF 62/76 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2
- INTS8 | c.238A>C p.I80L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KANK1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- KIAA1109 | c.9835G>A p.D3279N | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRATD1 | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- LRRC4 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 130/294 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MUC16 | c.19864C>A p.P6622T | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- MUC20 | c.1868G>T p.S623I | Missense Mutation (SNP) | VAF 116/597 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPAP1 | c.2809A>C p.S937R | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP210 | c.4287A>G p.R1429= | Splice Region (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- OR2T34 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PRPS1L1 | c.458_463del p.K153_W154del | In Frame Del (DEL) | VAF 104/229 reads (45%) | called by mutect2, pindel, varscan2
- PTPDC1 | c.1811T>C p.V604A (on ENST00000375360 / NM_177995.3; = p.V656A on NM_152422.4) | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC24A2 | c.650T>A p.L217H | Missense Mutation (SNP) | VAF 134/323 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD9 | c.2510C>A p.S837Y | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TSPAN14 | c.700T>G p.Y234D | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZNF395 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF512 | c.939A>G p.I313M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- ENC1 | c.441C>A p.T147= | Silent (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- EPS8L1 | c.411C>T p.F137= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV52381635; called by muse, mutect2, varscan2
- FAM83B | c.765C>T p.L255= | Silent (SNP) | VAF 71/133 reads (53%) | catalogued as rs767086906; called by muse, mutect2, varscan2
- IGHV2-70D | c.354G>A p.R118= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, varscan2
- IGLV3-25 | c.315C>T p.Y105= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs567556649; called by muse, varscan2
- ISLR2 | c.1551C>T p.G517= | Silent (SNP) | VAF 3/52 reads (6%) | called by muse, mutect2
- PGM2 | c.1731G>A p.G577= | Silent (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- SERPINA11 | c.366C>T p.L122= | Silent (SNP) | VAF 57/143 reads (40%) | catalogued as rs1204702266; called by muse, mutect2, varscan2
- TBL3 | c.811C>T p.L271= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV100224839; called by muse, mutect2, varscan2
- ABCB10 | c.*367G>A | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- ABHD18 | c.*379T>G | 3'UTR (SNP) | VAF 78/123 reads (63%) | called by muse, mutect2, varscan2
- AC026410.1 | n.1072C>T | RNA (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- ACP3 | c.*234G>A | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- ADH1B | c.*732A>G | 3'UTR (SNP) | VAF 57/177 reads (32%) | catalogued as rs1013991964; called by muse, mutect2, varscan2
- ALX3 | c.595-24C>G | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- ATXN7 | c.*1845_*1849del | 3'UTR (DEL) | VAF 31/100 reads (31%) | called by mutect2, pindel, varscan2
- BCL7A | chr12:122021402 C>G | 5'Flank (SNP) | VAF 62/130 reads (48%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- BTG1 | c.*891C>T | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- BTG2 | c.*420T>A | 3'UTR (SNP) | VAF 104/141 reads (74%) | called by muse, mutect2, varscan2
- CCDC144B | n.198G>A | RNA (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- CDH15 | c.*318G>A | 3'UTR (SNP) | VAF 78/163 reads (48%) | catalogued as rs1345274416; called by muse, mutect2, varscan2
- CLDN23 | c.-17C>A | 5'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- CLIP4 | c.*1873C>G | 3'UTR (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- COPS3 | c.762+348C>T | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- DENND1A | c.1489-10189T>C | Intron (SNP) | VAF 90/191 reads (47%) | called by muse, mutect2, varscan2
- EDC4 | c.3850-102T>C | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- GID4 | c.*2209G>A | 3'UTR (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- GLP1R | c.*1164G>A | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- GNA12 | c.526-29338G>A | Intron (SNP) | VAF 32/60 reads (53%) | catalogued as rs1395207908; called by muse, mutect2, varscan2
- GRM6 | c.*1734C>A | 3'UTR (SNP) | VAF 63/132 reads (48%) | called by muse, mutect2, varscan2
- HES2 | c.*1884C>A | 3'UTR (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- HTR1F | c.*280_*281dup | 3'UTR (INS) | VAF 17/49 reads (35%) | catalogued as rs199952254; called by mutect2, varscan2
- ITCH | chr20:34509032 G>A | 3'Flank (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1398+31G>T | Intron (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- KCTD20 | c.*3749G>A | 3'UTR (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- LASP1 | c.*1672C>T | 3'UTR (SNP) | VAF 62/159 reads (39%) | called by muse, mutect2, varscan2
- LNPK | c.*2440C>T | 3'UTR (SNP) | VAF 40/59 reads (68%) | called by muse, mutect2, varscan2
- MAPK9 | c.*1715C>G | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- MARCHF3 | c.*2121A>C | 3'UTR (SNP) | VAF 43/81 reads (53%) | called by muse, mutect2, varscan2
- MDM1 | c.*384G>A | 3'UTR (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- MMP16 | c.*3994T>C | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40525404 G>A | 5'Flank (SNP) | VAF 59/115 reads (51%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40525567 G>C | 5'Flank (SNP) | VAF 66/186 reads (35%) | called by muse, varscan2
- NEDD9 | c.460-5719T>A | Intron (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- PLAGL2 | c.*3902G>C | 3'UTR (SNP) | VAF 141/310 reads (45%) | called by muse, mutect2, varscan2
- PLAGL2 | c.*2523G>C | 3'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- PLXNA2 | c.*2975T>G | 3'UTR (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- PNRC1 | c.-88C>T | 5'UTR (SNP) | VAF 152/397 reads (38%) | catalogued as rs1284401396; called by muse, mutect2, varscan2
- PRKACB | c.47-14333C>T | Intron (SNP) | VAF 87/216 reads (40%) | called by muse, mutect2, varscan2
- PTK6 | c.*295G>A | 3'UTR (SNP) | VAF 16/270 reads (6%) | catalogued as rs895051043; called by muse, mutect2
- RAB11FIP3 | c.*799G>A | 3'UTR (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- RAB3B | c.*258C>T | 3'UTR (SNP) | VAF 35/109 reads (32%) | catalogued as rs538187538; called by muse, mutect2, varscan2
- RNF144B | c.-150A>T | 5'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, varscan2
- RNF182 | c.*291G>A | 3'UTR (SNP) | VAF 44/85 reads (52%) | called by muse, mutect2, varscan2
- RPL30 | c.22-37G>A | Intron (SNP) | VAF 65/150 reads (43%) | called by muse, mutect2, varscan2
- SCAMP4 | c.-42+43_-42+60delinsG | Intron (DEL) | VAF 20/103 reads (19%) | called by pindel, varscan2*
- SDR42E1 | c.69-187A>G | Intron (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
- SEMA5B | c.-38-14727G>A | Intron (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
- SGIP1 | c.*1092T>A | 3'UTR (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- SH3D19 | c.*896A>T | 3'UTR (SNP) | VAF 54/90 reads (60%) | called by muse, mutect2, varscan2
- SLK | c.*2586T>A | 3'UTR (SNP) | VAF 72/129 reads (56%) | called by muse, mutect2, varscan2
- SNRPB2 | c.*514G>A | 3'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- SOX1 | c.*437T>A | 3'UTR (SNP) | VAF 25/38 reads (66%) | called by muse, mutect2, varscan2
- SRSF11 | c.1023-112A>G | Intron (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- TERB2 | c.*381T>C | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- TNIP1 | c.847-63C>T | Intron (SNP) | VAF 64/97 reads (66%) | catalogued as rs574324382; called by muse, mutect2, varscan2
- USP44 | c.*212T>A | 3'UTR (SNP) | VAF 22/66 reads (33%) | called by muse, varscan2
- ZBP1 | c.-84C>T | 5'UTR (SNP) | VAF 9/26 reads (35%) | catalogued as rs931269334; called by muse, mutect2, varscan2
- ZNF738 | c.*730C>G | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
